Somatic mutation profile of tumor specimen MP2PRT-PAVTFR-TMP1-A (aliquot MP2PRT-PAVTFR-TMP1-A-1-0-D-A821-36) from MP2PRT case MP2PRT-PAVTFR, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (892 days).
Specimen MP2PRT-PAVTFR-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c41c426-1917-4559-b37d-34e47776df13.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVTFR-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVTFR-NB1-A-1-0-D-A821-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0d7ffe1d-cab7-42eb-b354-12b2862b16f1

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CXCL16 | c.146C>A p.P49Q | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV52645306; called by muse, mutect2
- JAG1 | c.2113+1G>A p.X705_splice | Splice Site (SNP) | VAF 116/241 reads (48%) | catalogued as rs1294950721, COSV54756325; called by muse, mutect2, varscan2
- SERPINA11 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 29/287 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs761615166; called by muse, mutect2, varscan2
- SLC45A4 | c.1357C>T p.R453C (on ENST00000517878 / NM_001286646.2; = p.R402C on NM_001080431.2) | Missense Mutation (SNP) | VAF 272/580 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as rs199873443, COSV50192554; called by muse, mutect2, varscan2
- ALPK3 | c.543G>T p.W181C | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- CES3 | c.1132T>A p.L378M | Missense Mutation (SNP) | VAF 107/363 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- IGKV1OR2-108 | c.332_353delinsCTATCCCC p.L111Pfs*? | Frame Shift Del (DEL) | VAF 41/201 reads (20%) | called by pindel, varscan2*
- SALL3 | c.1366C>T p.R456C | Missense Mutation (SNP) | VAF 87/781 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBXT | c.103G>A p.G35S | Missense Mutation (SNP) | VAF 30/893 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.411); called by muse, mutect2
- ZSCAN31 | c.958G>T p.E320* | Nonsense Mutation (SNP) | VAF 174/400 reads (44%) | called by muse, mutect2, varscan2
- ARHGEF10 | c.3393G>A p.T1131= (on ENST00000398564; = p.T1106= on NM_014629.4) | Silent (SNP) | VAF 72/690 reads (10%) | catalogued as rs780302201; called by muse, mutect2, varscan2
- LRRK2 | c.5877T>G p.L1959= | Silent (SNP) | VAF 24/502 reads (5%) | called by muse, mutect2
- MRC2 | c.2289C>T p.D763= | Silent (SNP) | VAF 16/309 reads (5%) | catalogued as rs1281693451; called by muse, mutect2
